Somatic mutation profile of tumor specimen C3N-02149-02 (aliquot CPT0118620006) from CPTAC case C3N-02149, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.4 years (23,517 days).
Specimen C3N-02149-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a4c32d-eec4-4a74-85ce-0a5e59bcc523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02149-31 (Blood Derived Normal), aliquot CPT0119870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1375949d-42ec-4560-ad82-85930c15419f

The open-access MAF lists 681 somatic variants for this specimen: 432 protein-altering or splice-affecting, 151 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 373, Silent 151, Intron 31, Nonsense Mutation 29, 3'UTR 20, RNA 17, 5'UTR 15, Frame Shift Del 11, 5'Flank 10, Splice Site 9, Splice Region 6, 3'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 136/940 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137854533, COSV55670877, COSV55673870; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JPH2 | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs587782951; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 124/623 reads (20%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOX3 | c.1423+1G>A p.X475_splice | Splice Site (SNP) | VAF 34/170 reads (20%) | catalogued as rs149402565; called by muse, varscan2
- ACP4 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54517804; called by muse, mutect2
- ANKRD34B | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58613748; called by muse, mutect2, varscan2
- AP1M2 | c.1052del p.G351Afs*5 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1490250889; called by mutect2, pindel, varscan2
- ARHGAP36 | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.396); catalogued as COSV99358157; called by muse, mutect2, varscan2
- ASTL | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1227100941; called by muse, mutect2, varscan2
- BOC | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.14); catalogued as COSV56351090; called by muse, mutect2, varscan2
- BORCS5 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761950808; called by mutect2, varscan2
- BRSK1 | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1453299590; called by muse, varscan2
- C1GALT1 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 55/321 reads (17%) | catalogued as COSV56178801; called by muse, mutect2, varscan2
- C6orf118 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs759679795; called by muse, mutect2
- CCNA1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV104371110; called by muse, mutect2, varscan2
- CEP89 | c.575C>A p.P192Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV99045257; called by muse, mutect2, varscan2
- CLCN1 | c.1592C>A p.A531E | Missense Mutation (SNP) | VAF 110/635 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990364; called by muse, mutect2, varscan2
- COL11A1 | c.4686A>C p.Q1562H | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV62173723; called by muse, mutect2
- COL11A2 | c.5027C>T p.P1676L (on ENST00000341947 / NM_080680.3; = p.P1569L on NM_080679.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs769990941, COSV100553451; called by muse, mutect2, varscan2
- COL15A1 | c.1503+1G>C p.X501_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as rs748308539; called by muse, mutect2
- COL5A3 | c.1169T>G p.F390C | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV53416975; called by muse, mutect2, varscan2
- CPSF4 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV99462516; called by muse, mutect2, varscan2
- CRB1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470882694, COSV66340298; called by muse, mutect2, varscan2
- DACT1 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1566511246; called by muse, mutect2
- DENND4B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1174520019, COSV63408135; called by muse, mutect2
- DHRS2 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51631409; called by muse, varscan2
- DIP2A | c.4213G>T p.G1405W | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596522; called by muse, mutect2, varscan2
- DPYSL5 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99981506; called by muse, mutect2, varscan2
- DRD1 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99062299; called by muse, mutect2, varscan2
- DUOXA2 | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as rs778830755, COSV50993154; called by mutect2, varscan2
- ELK1 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99901902; called by muse, mutect2, varscan2
- EPB42 | c.10+3G>T | Splice Region (SNP) | VAF 87/398 reads (22%) | catalogued as COSV100281790; called by muse, mutect2, varscan2
- EPS8L1 | c.1505G>A p.R502Q (on ENST00000201647 / NM_133180.3; = p.R375Q on NM_017729.3) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1399858854, COSV99136748; called by muse, mutect2, varscan2
- EPYC | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs116545939; called by muse, mutect2
- ERICH3 | c.3127del p.E1043Kfs*12 | Frame Shift Del (DEL) | VAF 53/298 reads (18%) | catalogued as COSV58610818, COSV58623053; called by mutect2, pindel, varscan2
- FASN | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 66/678 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1464240266, COSV60753431; called by muse, mutect2
- FBN2 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs142228933; called by muse, mutect2
- FCRL5 | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs752277017, COSV100709355; called by muse, mutect2
- FITM1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs1390059479; called by muse, mutect2, varscan2
- FKBP1A | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139306132; called by muse, mutect2
- FLNB | c.6034C>A p.L2012M | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55882220; called by mutect2, varscan2
- FOXG1 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV57396020; called by muse, mutect2, varscan2
- FRYL | c.6172G>T p.G2058* | Nonsense Mutation (SNP) | VAF 118/405 reads (29%) | catalogued as COSV99976634; called by muse, mutect2, varscan2
- GALC | c.2053C>A p.R685S | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as rs756141815, COSV54328595; ClinVar: uncertain significance; called by muse, varscan2
- GCAT | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs750944946; called by muse, mutect2
- GIMAP8 | c.1828del p.Q610Rfs*5 | Frame Shift Del (DEL) | VAF 61/364 reads (17%) | catalogued as COSV56230092, COSV56231287; called by mutect2, varscan2
- GNAZ | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1432454071; called by muse, mutect2
- GPHN | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 22/278 reads (8%) | catalogued as COSV59477976, COSV59479710; called by muse, mutect2
- GRID2 | c.1955T>C p.L652P | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56190673, COSV99943763; called by muse, mutect2
- HAL | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV54116811; called by muse, mutect2, varscan2
- HTR2C | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.246); catalogued as COSV52215689; called by muse, mutect2, varscan2
- HUWE1 | c.6826G>A p.E2276K | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV53350085, COSV53361121; called by muse, mutect2, varscan2
- IDI1 | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 16/421 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67282011; called by muse, mutect2
- IGFN1 | c.3076G>T p.G1026W (on ENST00000295591 / NM_001367841.1; = p.G3483W on NM_001164586.2) | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773930424, COSV55170465, COSV99812167; called by muse, mutect2, varscan2
- IGHV1-18 | c.298A>T p.M100L | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs376012484; called by muse, mutect2
- IL16 | c.2665C>T p.R889* (on ENST00000302987 / NM_172217.5; = p.R188* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100267492, COSV100267948; called by muse, mutect2, varscan2
- INHBA | c.1248G>T p.Q416H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV54223861; called by muse, mutect2, varscan2
- IPO7 | c.2611G>T p.G871* | Nonsense Mutation (SNP) | VAF 75/347 reads (22%) | catalogued as COSV65684508; called by muse, mutect2, varscan2
- IRX6 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs551322558; called by muse, mutect2
- KCNA5 | c.116C>A p.T39K | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); catalogued as rs1215071064, COSV99364072; called by muse, mutect2, varscan2
- KHDC4 | c.1134C>G p.Y378* | Nonsense Mutation (SNP) | VAF 25/345 reads (7%) | catalogued as COSV64165233; called by muse, mutect2
- KIAA1755 | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs781586678; called by muse, mutect2, varscan2
- LAMA1 | c.3721G>A p.V1241M | Missense Mutation (SNP) | VAF 55/634 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs763867369, COSV101056535; called by muse, mutect2
- LAMB4 | c.2868C>G p.F956L | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52714379, COSV99225464; called by muse, mutect2
- LAMC3 | c.4153G>T p.G1385* | Nonsense Mutation (SNP) | VAF 109/499 reads (22%) | catalogued as rs1434705364; called by muse, mutect2, varscan2
- LCE1B | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100780316; called by mutect2, varscan2
- MAP3K19 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs945623943; called by muse, mutect2
- MED6 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 25/232 reads (11%) | catalogued as COSV56451644; called by muse, mutect2, varscan2
- MMP24 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55768520; called by muse, mutect2, varscan2
- MUC5AC | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.01); catalogued as rs752586982, COSV62253579; called by muse, varscan2
- MUC5AC | c.15650C>A p.P5217Q | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100611578, COSV100611641; called by muse, mutect2, varscan2
- MYC | c.497G>T p.R166L (on ENST00000377970; = p.R181L on NM_002467.6) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); catalogued as COSV52373000; called by muse, mutect2
- NABP1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57139045; called by muse, mutect2
- NAT9 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99380441; called by muse, mutect2, varscan2
- NFASC | c.2152G>A p.E718K (on ENST00000339876 / NM_001378329.1; = p.E714K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as rs1436283667, COSV58385877; called by muse, mutect2, varscan2
- NLGN4X | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52024681, COSV99321784; called by muse, mutect2, varscan2
- NPNT | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1208017762; called by muse, mutect2, varscan2
- NUPR2 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV61408644, COSV61409503; called by muse, mutect2, varscan2
- OR13H1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs768787330, COSV100088293; called by muse, varscan2
- OR2B11 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV100276523; called by muse, mutect2, varscan2
- OR51G1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58969219; called by muse, mutect2, varscan2
- OR51Q1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56178066; called by muse, mutect2, varscan2
- OTOF | c.1480C>G p.R494G | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55512507, COSV55516456; called by muse, mutect2
- PARD6G | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs1036144243, COSV62060213; called by muse, mutect2, varscan2
- PAX2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 23/425 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs750238161; called by muse, mutect2
- PCDH15 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 35/532 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766969775, COSV57295026; called by muse, mutect2
- PCLO | c.12878C>G p.S4293C | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61680003; called by muse, mutect2, varscan2
- PDZD7 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs775908216; called by muse, mutect2, varscan2
- PGK2 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59164450; called by muse, mutect2, varscan2
- PLEKHM2 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779469077; called by muse, mutect2, varscan2
- PLK3 | c.209A>T p.K70M | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV64729000; called by muse, mutect2, varscan2
- PPP1R3C | c.81G>T p.R27S | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99491168; called by muse, mutect2
- PROM2 | c.2232G>T p.W744C | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024997779; called by muse, mutect2
- PSMC6 | c.1069C>A p.L357M (on ENST00000612399; = p.L343M on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1481240614; called by muse, mutect2, varscan2
- PTGFR | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1228267660; called by muse, mutect2
- PUS7 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV62678377; called by muse, mutect2, varscan2
- QSOX2 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62393545; called by muse, mutect2, varscan2
- RHCE | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as CM066600; called by muse, mutect2, varscan2
- RNF10 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs763897888, COSV58043218; called by muse, mutect2, varscan2
- RTL1 | c.2717A>T p.Y906F | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV66016909; called by muse, mutect2
- RYR1 | c.8197G>T p.G2733C | Missense Mutation (SNP) | VAF 56/632 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62097269; called by muse, mutect2
- SCN3A | c.2421G>T p.M807I | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51825823; called by muse, mutect2
- SGCZ | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV65998945, COSV66023450; called by muse, mutect2, varscan2
- SLC39A12 | c.1193G>T p.R398M | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV66198498; called by muse, mutect2, varscan2
- SLC39A12 | c.1573G>A p.G525S (on ENST00000377369 / NM_001145195.2; = p.G488S on NM_152725.3) | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101070075; called by muse, mutect2, varscan2
- SLC4A4 | c.1276G>T p.G426* (on ENST00000264485 / NM_001098484.3; = p.G382* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 89/423 reads (21%) | catalogued as COSV52625372; called by muse, mutect2, varscan2
- SLITRK2 | c.2254C>A p.P752T | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs932637565, COSV59428113; called by muse, mutect2, varscan2
- SLITRK3 | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53846279, COSV53848159; called by muse, mutect2, varscan2
- SOS2 | c.1969G>C p.D657H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs1184836351; called by muse, varscan2
- SPTA1 | c.5275G>C p.E1759Q | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV100935711; called by muse, mutect2
- SPTA1 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as rs766344444; called by muse, mutect2, varscan2
- SRGAP1 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs202173847; called by muse, mutect2, varscan2
- ST6GAL2 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 27/152 reads (18%) | PolyPhen benign (0.021); catalogued as COSV62416518; called by muse, mutect2
- STARD9 | c.13883C>A p.T4628K | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.71); catalogued as rs528447331; called by muse, mutect2, varscan2
- SULT2A1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55764410; called by muse, mutect2
- SYNJ1 | c.3470C>T p.T1157I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs762546216; called by muse, mutect2, varscan2
- TAAR5 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57799641, COSV99236884; called by muse, mutect2
- TAS2R39 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV71470941; called by muse, mutect2, varscan2
- TBC1D5 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781688564, COSV53753104; called by muse, mutect2, varscan2
- TCP10L | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV55828880; called by muse, mutect2, varscan2
- TEX26 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100994040; called by muse, mutect2, varscan2
- TGM6 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 68/638 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76286489; called by muse, mutect2
- THSD7A | c.1118C>G p.S373* | Nonsense Mutation (SNP) | VAF 36/446 reads (8%) | catalogued as COSV101448916; called by muse, mutect2
- TRAF1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.278); catalogued as COSV65868093; called by muse, mutect2, varscan2
- TRAJ5 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 39/204 reads (19%) | catalogued as rs753289191; called by muse, mutect2, varscan2
- TTC7B | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1404552787; called by muse, mutect2
- WASF3 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 39/588 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as rs201580275, COSV58965274; called by muse, mutect2
- XIRP2 | c.5258C>A p.S1753Y (on ENST00000628543; = p.S1928Y on NM_152381.6) | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1026215891, COSV54694993; called by muse, mutect2, varscan2
- ZEB1 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.429); catalogued as rs747913512; called by muse, mutect2, varscan2
- ZNF112 | c.2377C>G p.Q793E (on ENST00000337401 / NM_001083335.2; = p.Q787E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV100495508; called by muse, mutect2
- ZNF415 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV99701175; called by muse, mutect2
- ZNF521 | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64123960; called by muse, mutect2, varscan2
- ZNF804A | c.902G>T p.S301I | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV56472830; called by muse, mutect2
- ABCB4 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCD2 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- AC006059.2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, varscan2
- ACAN | c.2784G>T p.W928C | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACBD3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- ACP7 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ACTG1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 51/520 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ACTN2 | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 54/645 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ADAM19 | c.796G>T p.G266W | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTS12 | c.2867G>A p.C956Y | Missense Mutation (SNP) | VAF 66/529 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS2 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ADGRA1 | c.268A>T p.R90* | Nonsense Mutation (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- ADGRV1 | c.16562C>G p.A5521G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by mutect2, varscan2
- AGPAT4 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AK5 | c.169G>C p.D57H (on ENST00000354567 / NM_174858.3; = p.D31H on NM_012093.4) | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ANK1 | c.5365G>T p.A1789S | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.280G>C p.D94H (on ENST00000611781; = p.D38H on NM_052997.2) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD30B | c.1032A>C p.K344N | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ANKRD33 | c.60C>G p.F20L (on ENST00000340970 / NM_001304459.2; = p.F155L on NM_182608.4) | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ANKS4B | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- APAF1 | c.808A>G p.T270A (on ENST00000551964 / NM_181861.2; = p.T259A on NM_001160.3) | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- APOB | c.11820del p.L3941* | Frame Shift Del (DEL) | VAF 71/439 reads (16%) | called by mutect2, pindel, varscan2
- APOBR | c.1360G>A p.V454I (on ENST00000431282; = p.V463I on NM_018690.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOF | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 73/497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AREL1 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.022); called by muse, mutect2
- ARID1B | c.3442del p.E1148Sfs*50 | Frame Shift Del (DEL) | VAF 41/416 reads (10%) | called by mutect2, pindel, varscan2
- ATP12A | c.1684G>T p.G562W | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATR | c.2634-1G>T p.X878_splice | Splice Site (SNP) | VAF 46/305 reads (15%) | called by muse, mutect2, varscan2
- AXIN2 | c.2280G>T p.Q760H | Missense Mutation (SNP) | VAF 78/472 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AZGP1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BNC1 | c.2033T>C p.L678P | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- BROX | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2
- BRPF3 | c.2837G>T p.R946M | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- BRSK2 | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTBD16 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2
- BTBD7 | c.2494G>C p.G832R | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.598); called by muse, mutect2
- C1QTNF7 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- C2orf16 | c.4328G>A p.R1443K | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- CACNG1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADPS2 | c.3206A>G p.K1069R | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CAPN8 | c.1907del p.K636Rfs*34 | Frame Shift Del (DEL) | VAF 47/294 reads (16%) | called by mutect2, pindel, varscan2
- CBLL2 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CCDC103 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2
- CCDC105 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CCDC39 | c.2470C>A p.Q824K | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC40 | c.2311G>T p.V771F | Missense Mutation (SNP) | VAF 111/572 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CCDC71L | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CDC14C | c.914G>T p.C305F (on ENST00000428251; = p.C198F on NM_152627.3) | Missense Mutation (SNP) | VAF 66/527 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CDHR1 | c.2566A>G p.K856E | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); called by muse, mutect2
- CDS2 | c.149A>T p.D50V | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- CEP192 | c.4394G>T p.W1465L | Missense Mutation (SNP) | VAF 32/647 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CEP192 | c.4395G>T p.W1465C | Missense Mutation (SNP) | VAF 33/649 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CEP250 | c.3078G>C p.Q1026H | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CEP350 | c.3910A>T p.S1304C | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CFAP251 | c.206_207insGGAGGGGAAGTAGGA p.E68_D69insEEGK* | Nonsense Mutation (INS) | VAF 8/100 reads (8%) | called by muse*, mutect2*, pindel, varscan2*
- CFAP65 | c.2498C>A p.A833D | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2
- CHD4 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CHD6 | c.7070G>T p.S2357I | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CHRNB2 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CIT | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CITED2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CLASP1 | c.3683G>T p.G1228V | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR2 | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CNTNAP5 | c.1990C>A p.L664M | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COL11A1 | c.4030C>A p.P1344T | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CR2 | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 83/397 reads (21%) | called by muse, mutect2, varscan2
- CRADD | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CRB1 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 66/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CSMD3 | c.3463G>A p.A1155T (on ENST00000297405 / NM_001363185.1; = p.A1051T on NM_052900.3) | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CSRNP3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTLA4 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- CUL5 | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- CYP2R1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CYP4F2 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DACT1 | c.1165A>T p.S389C | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- DCDC2C | c.603C>A p.H201Q | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DCHS1 | c.3633C>A p.F1211L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DLG2 | c.2596T>A p.S866T | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DMXL1 | c.3874A>T p.K1292* | Nonsense Mutation (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.10102G>C p.D3368H (on ENST00000445597; = p.D4376H on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2
- DNAH17 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC5B | c.567A>T p.K189N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DUSP9 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- E2F1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 103/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHMT1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2
- ENOX2 | c.1733G>T p.G578V (on ENST00000338144 / NM_001382520.1; = p.G549V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 48/293 reads (16%) | called by muse, mutect2, varscan2
- EPHB6 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ERBB4 | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH6B | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESX1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- EXOC5 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EYS | c.3443G>T p.R1148I | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- EYS | c.2854T>A p.C952S | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- FAM20C | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- FAM71F1 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FAT3 | c.8589G>C p.M2863I | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGD5 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2
- FLT4 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FMNL1 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- FOXL1 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 93/481 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- FRMPD4 | c.1598C>A p.T533N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.203A>T p.K68I | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FSIP2 | c.5886C>A p.S1962R | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRG1 | c.420dup p.G141Wfs*7 | Frame Shift Ins (INS) | VAF 54/318 reads (17%) | called by pindel, varscan2
- GDF10 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GLIS3 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GPATCH1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- HELB | c.2980A>T p.M994L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGF | c.2125G>T p.V709L | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HHIPL1 | c.1620C>A p.Y540* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- HNF4A | c.441C>G p.S147R | Missense Mutation (SNP) | VAF 112/653 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HOXA2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IGKC | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 102/587 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1-8 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1132T>C p.Y378H | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IMPDH1 | c.1180G>T p.E394* (on ENST00000470772 / NM_001142573.2; = p.E480* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 111/485 reads (23%) | called by muse, mutect2, varscan2
- IQSEC3 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2
- ITGA4 | c.1895A>T p.Q632L | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- JADE2 | c.2355G>T p.M785I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- KCNA6 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB1 | c.1178T>G p.V393G | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCP | c.1423C>G p.P475A (on ENST00000620378; = p.P532A on NM_001366122.1) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1671 | c.1634A>T p.K545M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIAA2026 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIF1A | c.183A>T p.S61= | Splice Region (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- KIF3B | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- KIR2DL1 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHDC3 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRF2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KRT32 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- LAMA2 | c.1997A>G p.H666R | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LAMP3 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- LCOR | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LGR6 | c.1375G>T p.A459S (on ENST00000367278 / NM_001017403.1; = p.A407S on NM_021636.3) | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LMOD2 | c.236A>T p.K79I | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LPIN1 | c.849+1G>T p.X283_splice | Splice Site (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- LRCH1 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1B | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MCCC1 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 81/495 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MCTP2 | c.230C>G p.S77W | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MGAT5B | c.2099G>T p.C700F (on ENST00000569840 / NM_001199172.2; = p.C698F on NM_144677.3) | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MINDY1 | c.59T>A p.V20D | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMACHC | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 371/807 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MTCL1 | c.1385A>T p.E462V (on ENST00000306329 / NM_001378206.1; = p.E102V on NM_015210.4) | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MTMR12 | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUC3A | c.8864C>A p.A2955E | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MUC5B | c.5777C>A p.P1926Q | Missense Mutation (SNP) | VAF 105/649 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by mutect2, varscan2
- MYO18B | c.4545A>T p.A1515= | Splice Region (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- MYO7B | c.4477G>T p.A1493S | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NAV3 | c.3725A>T p.D1242V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NCKAP5 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- NCSTN | c.1699del p.V567Yfs*8 | Frame Shift Del (DEL) | VAF 46/297 reads (15%) | called by mutect2, pindel, varscan2
- NEUROD6 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 78/536 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- NFAM1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); called by muse, mutect2
- NID1 | c.1365C>A p.N455K | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NLGN4Y | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 49/658 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NLRP14 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP14 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 95/607 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NLRP8 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NOD2 | c.2032C>A p.L678M | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOP56 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NRG3 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- NRROS | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSMCE2 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NTRK2 | c.934A>T p.K312* | Nonsense Mutation (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- NUDT12 | c.519A>T p.E173D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- OASL | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- OR2T2 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 66/1616 reads (4%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.628); called by muse, mutect2
- OR51G1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5L1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR6A2 | c.509del p.G170Afs*44 | Frame Shift Del (DEL) | VAF 68/425 reads (16%) | called by mutect2, pindel, varscan2
- OR8H1 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OSBPL3 | c.1577T>G p.I526S | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- OTC | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- PADI3 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB9 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 74/471 reads (16%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1634A>T p.N545I | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PCDHGA3 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PCDHGA4 | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCDHGB3 | c.1862T>A p.L621Q | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PCTP | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2
- PDE8A | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PDZRN3 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIK3R5 | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLCXD3 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD3 | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- PLXDC2 | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by mutect2, varscan2
- POLA1 | c.2629A>T p.T877S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L2 | c.907T>A p.S303T | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POTEG | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 56/1472 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEI | c.2360A>T p.H787L | Missense Mutation (SNP) | VAF 80/606 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PPFIBP1 | c.1198-1G>T p.X400_splice (on ENST00000318304 / NM_177444.3; = p.X383_splice on NM_003622.4) | Splice Site (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- PPP2R1B | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2
- PRB2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, varscan2
- PRG4 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 100/591 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAG3 | c.1127T>A p.V376E | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM2 | c.2231G>T p.W744L | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROSER1 | c.767A>T p.Q256L | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2
- PRR30 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PSD | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- PSD4 | c.98dup p.R34Kfs*7 | Frame Shift Ins (INS) | VAF 26/257 reads (10%) | called by pindel, varscan2
- PTPRN2 | c.2470C>A p.P824T | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PXDNL | c.3046C>T p.H1016Y | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PYDC2 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PYHIN1 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RASA3 | c.2468T>A p.I823N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- RBBP6 | c.2267C>G p.S756C | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCC1L | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- REG3G | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RETREG2 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- RFTN1 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RIC8B | c.1162-2A>G p.X388_splice | Splice Site (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- RLN3 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- RNF133 | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.1355G>C p.S452T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RTP2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- S1PR4 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SACS | c.3163G>T p.D1055Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SAYSD1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN8A | c.5425G>T p.A1809S | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDC2 | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEL1L2 | c.1255+1G>T p.X419_splice | Splice Site (SNP) | VAF 42/215 reads (20%) | called by muse, mutect2, varscan2
- SEMA6D | c.574T>G p.L192V | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SENP7 | c.91-1G>T p.X31_splice | Splice Site (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.474); called by muse, mutect2
- SIGLEC12 | c.586G>T p.D196Y (on ENST00000291707 / NM_053003.4; = p.D78Y on NM_033329.2) | Missense Mutation (SNP) | VAF 44/523 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.261); called by muse, mutect2
- SIGLEC6 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIK3 | c.2177A>T p.E726V (on ENST00000445177 / NM_001366686.2; = p.E684V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SIN3B | c.2482A>T p.S828C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIRPA | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC16A1 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC26A4 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC27A4 | c.1199T>G p.V400G | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- SLC35D3 | c.665A>T p.D222V | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC39A1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- SLC9A2 | c.806_830del p.I269Tfs*11 | Frame Shift Del (DEL) | VAF 30/284 reads (11%) | called by mutect2, pindel
- SMARCC1 | c.2088G>T p.M696I | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SNTG1 | c.277+2T>A p.X93_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- SNX27 | c.1370C>G p.T457S | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SOS2 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.39); called by muse, varscan2
- SP8 | c.679G>T p.A227S (on ENST00000361443 / NM_198956.4; = p.A245S on NM_182700.6) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SPECC1 | c.222_229del p.K74Nfs*25 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- SSH3 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SSX3 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.28A>T p.I10F | Missense Mutation (SNP) | VAF 35/213 reads (16%) | PolyPhen benign (0.048); called by muse, mutect2, varscan2
- STEAP1 | c.241A>T p.I81L | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK11 | c.995G>A p.W332* | Nonsense Mutation (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- SYNE2 | c.11635A>T p.M3879L | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TANC2 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- TCEAL2 | c.176del p.K59Rfs*102 | Frame Shift Del (DEL) | VAF 67/241 reads (28%) | called by mutect2, pindel, varscan2
- TDRD15 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENM2 | c.3539C>A p.S1180Y (on ENST00000518659 / NM_001122679.2; = p.S948Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TET2 | c.3698G>T p.W1233L | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TF | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TIGD6 | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- TMEM120B | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOGARAM1 | c.3668C>G p.P1223R | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2
- TOM1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPST2 | c.1041G>T p.R347= | Splice Region (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- TRDMT1 | c.404A>C p.Q135P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.304); called by mutect2, varscan2
- TRGV8 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 73/578 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TRIL | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TRIM43B | c.199A>T p.N67Y | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TRIM58 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by mutect2, varscan2
- TSBP1 | c.549A>G p.A183= (on ENST00000617061; = p.A193= on NM_006781.5) | Splice Region (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- U2AF2 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2QL1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2Z | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); called by muse, mutect2
- UGT3A1 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3800G>C p.G1267A | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- UNC13A | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13C | c.1603T>A p.W535R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UPP1 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.096); called by muse, varscan2
- USH2A | c.10369A>T p.N3457Y | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- USHBP1 | c.1028A>T p.H343L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2
- UTP15 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, varscan2
- UXS1 | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- VMP1 | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- VN1R2 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- WDR97 | c.4284G>T p.W1428C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WHRN | c.1166+6G>T | Splice Region (SNP) | VAF 72/364 reads (20%) | called by muse, mutect2, varscan2
- WIPF1 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- XRCC2 | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ZFAT | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2
- ZMPSTE24 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 33/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF264 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZNF318 | c.73A>T p.S25C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF324B | c.1349A>T p.E450V | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF423 | c.1511A>T p.Q504L (on ENST00000563137 / NM_001379286.1; = p.Q496L on NM_015069.4) | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF438 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF528 | c.481A>T p.N161Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ZNF567 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF667 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2
- ZNF844 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.314); called by muse, mutect2
- ZSWIM5 | c.1123A>G p.R375G | Missense Mutation (SNP) | VAF 157/318 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ABCC9 | c.4329T>A p.T1443= | Silent (SNP) | VAF 171/541 reads (32%) | called by muse, mutect2, varscan2
- ACAP1 | c.1197G>A p.R399= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1194341126; called by muse, mutect2, varscan2
- ADAMTS4 | c.2073C>A p.S691= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- AFF2 | c.2703C>A p.S901= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, varscan2
- AHNAK | c.8358G>C p.V2786= | Silent (SNP) | VAF 17/313 reads (5%) | catalogued as rs1009147260; called by muse, mutect2
- AJAP1 | c.175C>A p.R59= | Silent (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
- AKAP4 | c.2385A>T p.G795= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1713C>A p.L571= (on ENST00000611781; = p.L515= on NM_052997.2) | Silent (SNP) | VAF 87/385 reads (23%) | called by muse, mutect2, varscan2
- ANKRD34B | c.225C>G p.A75= | Silent (SNP) | VAF 42/210 reads (20%) | called by muse, mutect2, varscan2
- ASF1B | c.84C>T p.F28= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs1158158213; called by muse, mutect2, varscan2
- ASIC1 | c.642G>T p.T214= | Silent (SNP) | VAF 78/242 reads (32%) | called by muse, mutect2, varscan2
- ATP12A | c.1683C>A p.G561= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV54525613; called by muse, mutect2
- AVPR1A | c.702C>A p.T234= | Silent (SNP) | VAF 61/486 reads (13%) | called by muse, mutect2, varscan2
- BCL11B | c.2346G>T p.P782= (on ENST00000357195 / NM_001282237.2; = p.P711= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs781050663; called by muse, mutect2, varscan2
- BPNT1 | c.537G>C p.G179= | Silent (SNP) | VAF 67/423 reads (16%) | catalogued as rs749514995; called by muse, mutect2, varscan2
- C4orf54 | c.3843C>A p.P1281= | Silent (SNP) | VAF 66/243 reads (27%) | catalogued as rs1409460906; called by muse, mutect2, varscan2
- C6orf118 | c.294C>G p.P98= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs146166260; called by muse, mutect2, varscan2
- CAPRIN2 | c.1959G>T p.P653= | Silent (SNP) | VAF 64/218 reads (29%) | called by muse, mutect2, varscan2
- CASTOR2 | c.249C>T p.S83= | Silent (SNP) | VAF 34/520 reads (7%) | catalogued as rs1390646615; called by muse, mutect2
- CBL | c.1203C>T p.C401= | Silent (SNP) | VAF 26/507 reads (5%) | catalogued as COSV50666816; called by muse, mutect2
- CD300E | c.255C>T p.L85= | Silent (SNP) | VAF 69/545 reads (13%) | catalogued as rs746024197, COSV60790157; called by muse, mutect2, varscan2
- CDH10 | c.1647C>A p.T549= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- CEP170B | c.1614C>T p.P538= (on ENST00000453495; = p.P467= on NM_015005.3) | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as rs772486458; called by muse, mutect2, varscan2
- CFAP74 | c.3690G>A p.L1230= | Silent (SNP) | VAF 36/292 reads (12%) | called by muse, mutect2, varscan2
- CHRNA1 | c.1212C>A p.P404= (on ENST00000261007 / NM_001039523.3; = p.P379= on NM_000079.4) | Silent (SNP) | VAF 35/312 reads (11%) | catalogued as rs756980389, COSV53683512; called by muse, mutect2, varscan2
- CIBAR2 | c.129G>T p.R43= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- CILP | c.399C>T p.Y133= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs200262966; called by muse, mutect2
- CNTNAP4 | c.2847G>A p.Q949= | Silent (SNP) | VAF 69/325 reads (21%) | called by muse, mutect2, varscan2
- COL18A1 | c.2625C>A p.S875= (on ENST00000359759 / NM_130444.3; = p.S640= on NM_030582.4) | Silent (SNP) | VAF 63/354 reads (18%) | called by muse, mutect2, varscan2
- CRB2 | c.1623T>G p.P541= | Silent (SNP) | VAF 36/225 reads (16%) | called by muse, mutect2, varscan2
- CREG2 | c.276C>A p.A92= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- CSF2RA | c.993A>T p.L331= | Silent (SNP) | VAF 34/498 reads (7%) | called by muse, mutect2
- CTNND2 | c.1350C>A p.T450= | Silent (SNP) | VAF 31/199 reads (16%) | catalogued as COSV58866932; called by muse, mutect2, varscan2
- CUL9 | c.396A>G p.E132= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- CXorf21 | c.330C>A p.T110= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs781525550; called by muse, mutect2, varscan2
- DAGLB | c.1035C>T p.I345= | Silent (SNP) | VAF 46/294 reads (16%) | called by muse, mutect2, varscan2
- DDX51 | c.423C>T p.A141= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as rs1293785183; called by muse, mutect2, varscan2
- DGKE | c.1335A>T p.I445= | Silent (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- DIP2B | c.366C>T p.P122= | Silent (SNP) | VAF 19/199 reads (10%) | catalogued as COSV56590133; called by muse, mutect2
- DLGAP2 | c.2808C>A p.A936= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- DNAH11 | c.9492C>A p.A3164= | Silent (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- DNAH6 | c.5232A>T p.L1744= | Silent (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- EIPR1 | c.678C>G p.A226= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2
- EVPL | c.4035G>A p.R1345= | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- EXOC5 | c.9C>T p.T3= | Silent (SNP) | VAF 27/250 reads (11%) | catalogued as rs1307406967; called by muse, mutect2, varscan2
- FLRT2 | c.873G>T p.L291= | Silent (SNP) | VAF 16/175 reads (9%) | catalogued as COSV58148927; called by muse, mutect2
- FSCN2 | c.558C>T p.L186= | Silent (SNP) | VAF 41/593 reads (7%) | called by muse, mutect2
- GABRR1 | c.858C>T p.L286= | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- GAL3ST4 | c.1198C>A p.R400= | Silent (SNP) | VAF 51/216 reads (24%) | catalogued as COSV57586612, COSV57587112; called by muse, mutect2, varscan2
- GAS2L2 | c.558C>A p.P186= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as rs1205516185; called by muse, mutect2, varscan2
- GML | c.162C>A p.R54= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- GMNC | c.549C>T p.P183= | Silent (SNP) | VAF 48/329 reads (15%) | catalogued as rs1223321237; called by muse, mutect2, varscan2
- GP6 | c.441G>A p.K147= | Silent (SNP) | VAF 80/571 reads (14%) | called by muse, mutect2, varscan2
- GPC1 | c.1509C>A p.V503= | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- GPR6 | c.126G>T p.A42= | Silent (SNP) | VAF 55/240 reads (23%) | catalogued as COSV99254402; called by muse, mutect2, varscan2
- GRAMD1B | c.1407C>A p.T469= | Silent (SNP) | VAF 74/315 reads (23%) | called by muse, mutect2, varscan2
- GRK7 | c.175C>T p.L59= | Silent (SNP) | VAF 55/382 reads (14%) | called by muse, mutect2, varscan2
- HDC | c.852C>T p.P284= | Silent (SNP) | VAF 79/353 reads (22%) | catalogued as rs762914264, COSV51074815; called by muse, mutect2, varscan2
- HOXA4 | c.954C>A p.S318= | Silent (SNP) | VAF 51/260 reads (20%) | called by muse, mutect2, varscan2
- HSD17B12 | c.546G>T p.G182= | Silent (SNP) | VAF 55/215 reads (26%) | called by muse, mutect2, varscan2
- HTR1E | c.717A>T p.T239= | Silent (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- IGFBP1 | c.72C>T p.A24= | Silent (SNP) | VAF 31/434 reads (7%) | called by muse, mutect2
- IGSF5 | c.96G>T p.V32= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- IL9 | c.31C>T p.L11= | Silent (SNP) | VAF 56/274 reads (20%) | called by muse, mutect2, varscan2
- KEL | c.844C>T p.L282= | Silent (SNP) | VAF 30/402 reads (7%) | catalogued as COSV62338120; called by muse, mutect2
- KLHL40 | c.1551G>A p.G517= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs146752497; called by muse, mutect2, varscan2
- KLRG2 | c.297C>A p.A99= | Silent (SNP) | VAF 34/204 reads (17%) | called by muse, mutect2, varscan2
- KRT36 | c.831C>A p.R277= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- LIPN | c.15T>A p.L5= | Silent (SNP) | VAF 52/234 reads (22%) | called by muse, mutect2, varscan2
- LRRTM1 | c.468C>T p.L156= | Silent (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- LRRTM4 | c.1059A>C p.A353= | Silent (SNP) | VAF 39/213 reads (18%) | called by mutect2, varscan2
- MAGEA4 | c.72C>A p.G24= | Silent (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- MALRD1 | c.5079G>T p.R1693= | Silent (SNP) | VAF 41/292 reads (14%) | called by muse, varscan2
- MAP3K10 | c.1308G>T p.R436= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- MEIOC | c.2040T>C p.F680= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- MUC6 | c.6780C>G p.T2260= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV70133944; called by muse, mutect2, varscan2
- MYO1G | c.690C>T p.F230= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- NFATC1 | c.529C>T p.L177= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99502618; called by muse, mutect2, varscan2
- NLRC5 | c.121C>T p.L41= | Silent (SNP) | VAF 36/436 reads (8%) | called by muse, mutect2
- NOS3 | c.888A>T p.P296= | Silent (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- NRG2 | c.705C>A p.T235= | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2
- NRXN2 | c.2616C>A p.S872= | Silent (SNP) | VAF 76/287 reads (26%) | catalogued as COSV55458170; called by muse, mutect2, varscan2
- OBSCN | c.20997G>C p.G6999= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV63610441; called by muse, mutect2, varscan2
- OR10A5 | c.231C>A p.V77= | Silent (SNP) | VAF 122/590 reads (21%) | catalogued as rs1388234826; called by muse, mutect2, varscan2
- OR13C2 | c.402C>T p.I134= | Silent (SNP) | VAF 24/229 reads (10%) | called by muse, varscan2
- OR13C9 | c.402C>T p.I134= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as COSV52243325; called by muse, mutect2, varscan2
- OR2B11 | c.144C>A p.A48= | Silent (SNP) | VAF 98/416 reads (24%) | called by muse, mutect2, varscan2
- OR51B5 | c.105C>A p.S35= | Silent (SNP) | VAF 41/187 reads (22%) | called by muse, mutect2, varscan2
- OR6K6 | c.414A>G p.T138= (on ENST00000368144; = p.T114= on NM_001005184.1) | Silent (SNP) | VAF 37/268 reads (14%) | called by muse, mutect2, varscan2
- OR8B12 | c.798C>T p.P266= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as COSV60912342; called by muse, mutect2, varscan2
- OTOGL | c.4395A>G p.L1465= (on ENST00000547103; = p.L1456= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/265 reads (12%) | catalogued as rs1275467307; called by muse, mutect2, varscan2
- PADI3 | c.78C>A p.L26= | Silent (SNP) | VAF 57/298 reads (19%) | catalogued as COSV64935210, COSV64935259; called by muse, mutect2, varscan2
- PCDHA4 | c.1489C>A p.R497= | Silent (SNP) | VAF 167/628 reads (27%) | catalogued as rs369858637; called by muse, mutect2, varscan2
- PCDHGA7 | c.1359C>A p.P453= | Silent (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- PGAM4 | c.741T>A p.A247= | Silent (SNP) | VAF 54/185 reads (29%) | called by muse, mutect2, varscan2
- PIGA | c.825G>T p.R275= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- PIM2 | c.342G>T p.L114= | Silent (SNP) | VAF 56/156 reads (36%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2355C>T p.S785= (on ENST00000283426; = p.S1141= on NM_052909.5) | Silent (SNP) | VAF 77/229 reads (34%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1743G>A p.T581= | Silent (SNP) | VAF 56/246 reads (23%) | catalogued as rs369889571; called by muse, mutect2, varscan2
- PMP2 | c.129C>A p.I43= | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- PRB2 | c.120C>A p.P40= | Silent (SNP) | VAF 50/223 reads (22%) | called by muse, varscan2
- PRDM2 | c.1974C>T p.P658= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- PURB | c.549C>T p.R183= | Silent (SNP) | VAF 60/233 reads (26%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.552C>T p.D184= | Silent (SNP) | VAF 100/563 reads (18%) | called by muse, mutect2, varscan2
- RAMP3 | c.315C>A p.T105= | Silent (SNP) | VAF 114/510 reads (22%) | catalogued as rs1043997154; called by muse, mutect2, varscan2
- REXO1 | c.2355C>T p.T785= | Silent (SNP) | VAF 46/478 reads (10%) | catalogued as rs375017589; called by muse, mutect2
- RIMS2 | c.2934T>C p.N978= (on ENST00000666250 / NM_001348490.2; = p.N786= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as rs766062874, COSV51650302; called by muse, mutect2
- RPP38 | c.204A>G p.K68= | Silent (SNP) | VAF 68/299 reads (23%) | called by muse, mutect2, varscan2
- RTL4 | c.225C>A p.L75= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- RYR2 | c.10176A>T p.A3392= | Silent (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- SCLT1 | c.1275G>T p.V425= | Silent (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- SCML2 | c.36C>G p.V12= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1247475828; called by muse, mutect2, varscan2
- SCN1A | c.666A>T p.R222= | Silent (SNP) | VAF 40/425 reads (9%) | called by muse, mutect2
- SDHAF1 | c.72G>A p.G24= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs1374503062; called by muse, mutect2, varscan2
- SLC12A7 | c.1440G>T p.V480= | Silent (SNP) | VAF 94/349 reads (27%) | called by muse, mutect2, varscan2
- SLC12A8 | c.105G>A p.E35= | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as rs1245293634; called by muse, mutect2, varscan2
- SLC22A24 | c.828T>C p.S276= | Silent (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- SLC24A3 | c.1365G>T p.P455= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as rs778560980, COSV60131872; called by muse, mutect2, varscan2
- SLC6A3 | c.1245G>T p.L415= | Silent (SNP) | VAF 70/636 reads (11%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1315C>A p.R439= | Silent (SNP) | VAF 77/522 reads (15%) | catalogued as CM119605, COSV100116939; called by muse, mutect2, varscan2
- SLCO5A1 | c.571C>A p.R191= | Silent (SNP) | VAF 60/315 reads (19%) | called by muse, mutect2, varscan2
- SPANXD | c.216C>A p.A72= | Silent (SNP) | VAF 76/379 reads (20%) | catalogued as COSV65152945; called by muse, mutect2, varscan2
- SPARCL1 | c.1113C>A p.A371= | Silent (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.552G>T p.P184= | Silent (SNP) | VAF 47/258 reads (18%) | catalogued as COSV57792698; called by muse, mutect2, varscan2
- SRBD1 | c.2535G>T p.G845= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- SREK1 | c.1476G>A p.G492= | Silent (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- SSTR5 | c.756G>T p.V252= | Silent (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- SSU72P8 | c.447C>T p.I149= | Silent (SNP) | VAF 67/308 reads (22%) | called by muse, varscan2
- STK10 | c.498C>T p.T166= | Silent (SNP) | VAF 48/223 reads (22%) | called by muse, mutect2, varscan2
- STXBP5 | c.636G>A p.L212= | Silent (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- SULT6B1 | c.759C>A p.V253= (on ENST00000535679 / NM_001367551.1; = p.V215= on NM_001032377.2) | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs137864268, COSV53193975; called by muse, mutect2, varscan2
- SYNE2 | c.7977G>T p.R2659= | Silent (SNP) | VAF 67/507 reads (13%) | called by muse, mutect2, varscan2
- TBCCD1 | c.585A>G p.S195= | Silent (SNP) | VAF 67/446 reads (15%) | called by muse, mutect2, varscan2
- TCF15 | c.597A>G p.R199= | Silent (SNP) | VAF 82/317 reads (26%) | called by muse, mutect2, varscan2
- TECPR1 | c.2184G>T p.P728= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs775757627, COSV65782979, COSV65784091; called by muse, mutect2, varscan2
- TEKT4 | c.99C>T p.S33= | Silent (SNP) | VAF 37/264 reads (14%) | catalogued as rs1553394474; called by muse, mutect2, varscan2
- TGM6 | c.1773C>A p.T591= | Silent (SNP) | VAF 52/426 reads (12%) | called by muse, mutect2, varscan2
- TINAG | c.162G>C p.G54= | Silent (SNP) | VAF 24/410 reads (6%) | called by muse, mutect2
- TMEM132C | c.1903C>A p.R635= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV59428446; called by muse, mutect2
- TMPRSS2 | c.195C>T p.V65= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs778999405; called by muse, mutect2, varscan2
- TRIM66 | c.402G>A p.E134= | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as COSV55124638; called by muse, mutect2, varscan2
- TTC21B | c.3678T>C p.H1226= | Silent (SNP) | VAF 42/344 reads (12%) | called by muse, mutect2, varscan2
- U2AF2 | c.1083G>T p.P361= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100454012, COSV58274247; called by muse, mutect2, varscan2
- VAV1 | c.1206G>T p.R402= | Silent (SNP) | VAF 47/257 reads (18%) | called by muse, mutect2, varscan2
- VWCE | c.669G>A p.E223= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- WDFY4 | c.6249C>A p.P2083= | Silent (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- WDR62 | c.3477C>A p.T1159= | Silent (SNP) | VAF 40/630 reads (6%) | catalogued as COSV99544198; called by muse, mutect2
- XDH | c.657G>C p.L219= | Silent (SNP) | VAF 22/542 reads (4%) | catalogued as COSV101051953; called by muse, mutect2
- ZDBF2 | c.3762T>A p.A1254= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2, varscan2
- ZIM3 | c.1272T>C p.C424= | Silent (SNP) | VAF 24/393 reads (6%) | catalogued as COSV54141640, COSV54146048; called by muse, mutect2
- ZNF469 | c.8154G>A p.G2718= (on ENST00000437464; = p.G2746= on NM_001367624.2) | Silent (SNP) | VAF 103/443 reads (23%) | catalogued as rs372014903; called by muse, mutect2, varscan2
- ABCC8 | c.4119+39G>T | Intron (SNP) | VAF 50/220 reads (23%) | called by muse, mutect2, varscan2
- ABCG1 | c.287-11024G>T | Intron (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- AC011525.1 | n.996C>A | RNA (SNP) | VAF 10/85 reads (12%) | catalogued as rs1006955111; called by muse, mutect2, varscan2
- AC068587.4 | n.683+5021G>A | Intron (SNP) | VAF 30/325 reads (9%) | catalogued as rs1280951232; called by muse, mutect2, varscan2
- AC069528.1 | n.390A>T | RNA (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- AC073310.1 | n.255G>T | RNA (SNP) | VAF 35/339 reads (10%) | called by muse, mutect2, varscan2
- AC083899.1 | n.3264G>T | RNA (SNP) | VAF 29/159 reads (18%) | catalogued as rs1366692721; called by muse, mutect2, varscan2
- AC083899.1 | n.3265G>T | RNA (SNP) | VAF 30/165 reads (18%) | called by muse, mutect2, varscan2
- AGA | c.*75C>G | 3'UTR (SNP) | VAF 29/268 reads (11%) | called by muse, mutect2, varscan2
- AGAP7P | n.882G>A | RNA (SNP) | VAF 36/930 reads (4%) | catalogued as rs372742209; called by muse, mutect2
- AL035696.1 | n.337G>T | RNA (SNP) | VAF 71/340 reads (21%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824508 G>A | 5'Flank (SNP) | VAF 30/205 reads (15%) | catalogued as rs950303225; called by muse, mutect2, varscan2
- ARHGAP45 | c.90+149G>T | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- ARID5B | c.734-1437A>C | Intron (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- BAALC | c.*1C>A | 3'UTR (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- BIRC8 | n.1140G>T | RNA (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- BLK | c.1030-397C>G | Intron (SNP) | VAF 32/202 reads (16%) | called by muse, mutect2, varscan2
- CACTIN | c.*227C>T | 3'UTR (SNP) | VAF 60/295 reads (20%) | called by muse, mutect2, varscan2
- CLEC2D | c.462-911A>T | Intron (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- COPS7B | c.238+275G>T | Intron (SNP) | VAF 16/196 reads (8%) | catalogued as rs570197192; called by muse, mutect2
- CPOX | c.811+58G>C | Intron (SNP) | VAF 56/245 reads (23%) | called by muse, mutect2, varscan2
- CSNK1D | c.1057+98A>T | Intron (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- CYP17A1 | c.-9C>A | 5'UTR (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- DCAF17 | c.*1132C>G | 3'UTR (SNP) | VAF 16/241 reads (7%) | called by muse, mutect2
- DCAF17 | c.*1133T>G | 3'UTR (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- DEPDC5 | c.*980G>T | 3'UTR (SNP) | VAF 28/400 reads (7%) | catalogued as COSV56702283; called by muse, mutect2
- DYNLRB1 | c.3+259G>T | Intron (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- EPOR | c.-54G>T | 5'UTR (SNP) | VAF 41/165 reads (25%) | catalogued as rs1485638893; called by muse, mutect2, varscan2
- FAIM2 | c.-7C>A | 5'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2
- FAM160A2 | c.2215+225C>G | Intron (SNP) | VAF 28/366 reads (8%) | called by muse, mutect2
- FAM161B | c.-117G>A | 5'UTR (SNP) | VAF 21/243 reads (9%) | catalogued as rs1281669628; called by muse, mutect2
- FAM86B3P | n.524A>G | RNA (SNP) | VAF 43/194 reads (22%) | called by muse, mutect2, varscan2
- FBN1 | c.*50T>A | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, varscan2
- FGFR4 | c.1057+45G>T | Intron (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- FKTN | c.780+46G>T | Intron (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- GPATCH4 | chr1:156595207 C>G | 3'Flank (SNP) | VAF 17/250 reads (7%) | called by muse, mutect2
- HSP90AA4P | n.2210C>A | RNA (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- HSPA4 | c.-5G>T | 5'UTR (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.-23A>T | 5'UTR (SNP) | VAF 24/252 reads (10%) | catalogued as rs1569011440; called by muse, mutect2
- IGLV8OR8-1 | n.160C>A | RNA (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.*330C>G | 3'UTR (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- KNCN | c.*390C>A | 3'UTR (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2
- MCFD2 | c.149+50G>T | Intron (SNP) | VAF 52/297 reads (18%) | called by muse, mutect2, varscan2
- MFSD14C | n.690G>T | RNA (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- MGAT4C | c.-95del | 5'UTR (DEL) | VAF 35/184 reads (19%) | called by mutect2, pindel, varscan2
- MRPS36P1 | chr3:6770010 G>T | 3'Flank (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- MTBP | chr8:120445411 del GC | 5'Flank (DEL) | VAF 18/152 reads (12%) | called by pindel, varscan2
- MYEF2 | c.1138+35A>G | Intron (SNP) | VAF 34/134 reads (25%) | catalogued as rs1361835592; called by muse, mutect2, varscan2
- NEU4 | chr2:241809147 T>A | 5'Flank (SNP) | VAF 23/264 reads (9%) | called by muse, mutect2
- NFATC4 | c.101-106G>T | Intron (SNP) | VAF 60/313 reads (19%) | called by muse, mutect2, varscan2
- NKD2 | c.*57G>T | 3'UTR (SNP) | VAF 112/318 reads (35%) | called by muse, varscan2
- NPAS3 | chr14:32939312 G>T | 5'Flank (SNP) | VAF 66/223 reads (30%) | catalogued as COSV100389793; called by muse, mutect2, varscan2
- NR1H4 | chr12:100563532 T>A | 3'Flank (SNP) | VAF 31/184 reads (17%) | catalogued as COSV51850719; called by muse, mutect2, varscan2
- OR10D1P | n.217T>A | RNA (SNP) | VAF 134/499 reads (27%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5121150 C>A | 3'Flank (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- OR6W1P | n.753G>T | RNA (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233228 C>A | 5'Flank (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- OVCH1-AS1 | n.350G>T | RNA (SNP) | VAF 45/163 reads (28%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91541C>A | Intron (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- PLA2G4C | c.*36G>T | 3'UTR (SNP) | VAF 18/172 reads (10%) | catalogued as rs772248895; called by muse, mutect2, varscan2
- PML | c.1710+593G>C | Intron (SNP) | VAF 74/313 reads (24%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30057234 G>A | 5'Flank (SNP) | VAF 59/300 reads (20%) | catalogued as rs1293143844; called by muse, mutect2, varscan2
- PRDM2 | c.*49A>G | 3'UTR (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- PRSS37 | c.430+211G>T | Intron (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- RAB4A | c.-87del | 5'UTR (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34158663 C>A | 5'Flank (SNP) | VAF 53/192 reads (28%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159320 G>C | 5'Flank (SNP) | VAF 17/120 reads (14%) | catalogued as rs201829623; called by muse, mutect2, varscan2
- ROBO2 | c.*32A>T | 3'UTR (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- RP1L1 | c.*40C>G | 3'UTR (SNP) | VAF 47/197 reads (24%) | catalogued as COSV101222838; called by muse, mutect2, varscan2
- RPGR | c.2520+164G>T | Intron (SNP) | VAF 50/169 reads (30%) | catalogued as COSV58840115; called by muse, mutect2, varscan2
- RPL13A | chr19:49487535 C>A | 5'Flank (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- SAG | c.649-10A>G | Intron (SNP) | VAF 28/360 reads (8%) | called by muse, mutect2
- SEC14L1 | c.2042+33G>T | Intron (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- SEC61G | c.-26T>A | 5'UTR (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- SKAP2 | c.-22G>T | 5'UTR (SNP) | VAF 44/224 reads (20%) | called by muse, mutect2, varscan2
- SKI | c.-18G>T | 5'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- SLC22A20P | n.580A>T | RNA (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- SSPOP | n.5386C>T | RNA (SNP) | VAF 55/298 reads (18%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.602+25G>A | Intron (SNP) | VAF 204/445 reads (46%) | catalogued as rs367570974; called by muse, mutect2, varscan2
- TBCE | c.1210+20C>A | Intron (SNP) | VAF 33/386 reads (9%) | called by muse, mutect2
- TEPSIN | c.-38C>A | 5'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2246G>T | 3'UTR (SNP) | VAF 32/122 reads (26%) | called by muse, varscan2
- TIE1 | c.1043-72G>T | Intron (SNP) | VAF 232/525 reads (44%) | catalogued as rs565947974; called by muse, mutect2, varscan2
- TINAG | c.624+50T>C | Intron (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- TJP2 | c.2567-64del | Intron (DEL) | VAF 53/260 reads (20%) | called by mutect2, pindel, varscan2
- TMEM135 | c.*1584A>T | 3'UTR (SNP) | VAF 134/431 reads (31%) | called by muse, mutect2, varscan2
- TMEM145 | c.1402-12C>A | Intron (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- TMEM71 | c.-5C>A | 5'UTR (SNP) | VAF 32/228 reads (14%) | called by muse, varscan2
- TRIM16L | c.-7G>T | 5'UTR (SNP) | VAF 77/342 reads (23%) | called by muse, mutect2, varscan2
- ULBP2 | c.*73G>C | 3'UTR (SNP) | VAF 10/178 reads (6%) | catalogued as rs1413022123, COSV100951212; called by muse, mutect2
- UTS2B | c.*10T>A | 3'UTR (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- VPS8 | c.1735-3758A>G | Intron (SNP) | VAF 31/156 reads (20%) | catalogued as rs375757998; called by muse, mutect2, varscan2
- XIAP | c.*3259A>G | 3'UTR (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- XIAP | c.*4551A>G | 3'UTR (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- ZBTB8OS | c.364-19A>T | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs1226140140; called by mutect2, varscan2
- ZNF324B | chr19:58451617 G>A | 5'Flank (SNP) | VAF 16/225 reads (7%) | catalogued as rs1047847890; called by muse, mutect2
- ZNF398 | c.-6A>T | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- ZNF517 | chr8:144810194 G>T | 3'Flank (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
